Somatic mutation profile of tumor specimen TCGA-2Y-A9GV-01A (aliquot TCGA-2Y-A9GV-01A-11D-A382-10) from TCGA case TCGA-2Y-A9GV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 54.8 years (20,011 days).
Specimen TCGA-2Y-A9GV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc250b7b-e636-4596-a506-6de4060f6e31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GV-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GV-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d51a77e6-432a-41c0-810b-a5d335e1ba0f

The open-access MAF lists 69 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 11, Frame Shift Ins 2, Intron 2, Nonsense Mutation 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99203869; called by muse, mutect2, varscan2
- ADGRE1 | c.2614T>A p.S872T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV99165725; called by muse, mutect2, varscan2
- ADGRV1 | c.15770T>C p.I5257T | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV101316352; called by muse, mutect2, varscan2
- AIFM1 | c.1088T>A p.V363E | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99781362; called by muse, mutect2, varscan2
- ATAD5 | c.3721T>A p.F1241I | Missense Mutation (SNP) | VAF 113/363 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100430163; called by muse, mutect2, varscan2
- ATP13A3 | c.2702C>T p.S901L | Missense Mutation (SNP) | VAF 18/523 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs941648698, COSV55471477; called by muse, mutect2
- BMERB1 | c.177A>C p.K59N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV100253342; called by muse, mutect2
- CAMLG | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.149); catalogued as COSV99777812; called by muse, mutect2, varscan2
- CAVIN1 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs758025496, COSV100824596; called by muse, mutect2, varscan2
- CCR6 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100551181; called by muse, mutect2, varscan2
- CES2 | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV100399380; called by muse, mutect2, varscan2
- CSMD3 | c.1957A>G p.K653E (on ENST00000297405 / NM_001363185.1; = p.K549E on NM_052900.3) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99844505; called by muse, mutect2, varscan2
- DALRD3 | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV100482893; called by muse, mutect2, varscan2
- DNAH1 | c.4115C>G p.T1372R | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV101326833; called by muse, mutect2, varscan2
- DYM | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV99493951; called by muse, mutect2, varscan2
- DYRK3 | c.1660A>G p.K554E | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV100895802; called by muse, mutect2, varscan2
- EIF2AK4 | c.4239C>G p.I1413M | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99775260; called by muse, mutect2, varscan2
- EPM2A | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 268/855 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs1239406349, COSV100837604; called by muse, varscan2
- FMR1 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 192/628 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503710, COSV99503872; called by muse, mutect2, varscan2
- GNPTAB | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100172310; called by muse, mutect2, varscan2
- GPM6A | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99705149; called by muse, mutect2, varscan2
- GRIK4 | c.376T>C p.F126L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV101483710; called by muse, mutect2, varscan2
- IRS4 | c.1964T>A p.L655H | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100929674; called by muse, mutect2
- IRX4 | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99181241; called by muse, mutect2, varscan2
- ITGB3 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 390/1232 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as COSV101457661; called by muse, mutect2, varscan2
- JPH4 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs754712369, COSV100689375; called by muse, mutect2, varscan2
- KHDC4 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV100850846; called by muse, mutect2, varscan2
- KIF26A | c.3620A>T p.H1207L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV100181487; called by muse, mutect2, varscan2
- KRT79 | c.520T>C p.W174R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100398529; called by muse, mutect2, varscan2
- KRTAP27-1 | c.481T>C p.C161R | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.742); catalogued as rs867048756, COSV101239761; called by muse, mutect2, varscan2
- LRRC6 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99138421; called by muse, mutect2, varscan2
- MOGAT1 | c.665T>G p.V222G | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101485122; called by muse, mutect2, varscan2
- NAXD | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV100010639; called by muse, mutect2, varscan2
- NRARP | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV100751964; called by muse, mutect2, varscan2
- OR10K2 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.424); catalogued as rs1357247573, COSV100149628; called by muse, mutect2
- OR2M2 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV100677298; called by muse, mutect2
- P4HA3 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192450731, COSV100525864, COSV59043546; called by muse, mutect2, varscan2
- PHIP | c.1003T>C p.F335L | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV99244767; called by muse, mutect2, varscan2
- POLD2 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789699; called by muse, mutect2, varscan2
- PPRC1 | c.3758C>G p.S1253C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99531977; called by muse, mutect2, varscan2
- PREX1 | c.890T>G p.L297R | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906716; called by muse, mutect2, varscan2
- RGS6 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV100666856; called by muse, mutect2, varscan2
- SLC23A2 | c.1024A>T p.K342* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | catalogued as COSV100595212; called by muse, mutect2
- SPOCD1 | c.2970G>C p.W990C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as COSV99930264, COSV99930339; called by muse, mutect2, varscan2
- TEX35 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1420133817, COSV99274103; called by muse, mutect2, varscan2
- TMEM150A | c.396G>T p.Q132H (on ENST00000334462 / NM_001031738.3; = p.Q79H on NM_153342.3) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100110567, COSV100110590; called by muse, mutect2, varscan2
- TNFRSF10A | c.377G>T p.S126I | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99646342; called by muse, mutect2, varscan2
- TRIP12 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); catalogued as rs1438011799, COSV99390828; called by muse, mutect2, varscan2
- TSPYL1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63994035, COSV63994239; called by muse, mutect2, varscan2
- TTBK2 | c.2377T>G p.L793V | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV99142290; called by muse, mutect2, varscan2
- ZNF527 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs561350704, COSV100648769; called by muse, mutect2, varscan2
- ZNF780A | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100575103; called by muse, mutect2, varscan2
- ABCC12 | c.2564_2581del p.Y855_V860del | In Frame Del (DEL) | VAF 25/96 reads (26%) | called by mutect2, pindel, varscan2
- ATP1A1 | c.1373dup p.C459Vfs*36 | Frame Shift Ins (INS) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- NRBP2 | c.1447_1462dup p.F488Yfs*95 | Frame Shift Ins (INS) | VAF 25/114 reads (22%) | called by mutect2, varscan2
- APLP1 | c.903T>A p.P301= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV99697870; called by muse, mutect2, varscan2
- ARHGEF16 | c.1254C>T p.S418= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs766063142, COSV101000568; called by muse, mutect2, varscan2
- HLCS | c.2076T>C p.S692= | Silent (SNP) | VAF 154/1812 reads (8%) | catalogued as COSV99293542; called by muse, mutect2
- MARCHF10 | c.1200T>A p.P400= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV100248517; called by muse, mutect2, varscan2
- PCDHGB1 | c.1476G>A p.L492= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99544959; called by muse, mutect2, varscan2
- SLC22A14 | c.135C>T p.H45= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV56199848; called by muse, mutect2, varscan2
- SLC34A3 | c.120G>T p.G40= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as COSV100746710; called by muse, mutect2, varscan2
- SLIT3 | c.2754T>C p.N918= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as COSV100269346; called by muse, mutect2, varscan2
- TNFRSF10A | c.378C>T p.S126= | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as rs148868243, COSV55325949; called by muse, mutect2, varscan2
- ZNF143 | c.141C>T p.G47= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs761035816, COSV55181230; called by muse, mutect2, varscan2
- ZNF225 | c.864C>T p.F288= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV99489570; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/42 reads (14%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- PTMA | c.46-1143G>A | Intron (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100398448; called by muse, mutect2, varscan2
- SSPOP | n.7238C>A | RNA (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100022543, COSV100022887; called by muse, mutect2, varscan2
